Somatic mutation profile of tumor specimen 0DO5FO from CCDI case PBCBSN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.4 years (7,449 days).
Specimen 0DO5FO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56579f4b-5978-477b-b490-f28244596e50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO5DX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/544ceea6-3fa6-49db-92c3-c394e49a1dd8

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 2, Translation Start Site 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPNE8 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 76/908 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs1199950809; called by muse, mutect2
- GDPGP1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773297870; called by muse, mutect2
- CSPG4 | c.2943A>T p.E981D | Missense Mutation (SNP) | VAF 51/577 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2
- EGLN1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 29/1032 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- ESRP2 | c.213C>A p.H71Q | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- CASP4 | c.-42G>A | 5'UTR (SNP) | VAF 124/1419 reads (9%) | called by muse, mutect2
- MMP15 | c.-33G>T | 5'UTR (SNP) | VAF 66/375 reads (18%) | called by muse, mutect2, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 15/163 reads (9%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- USP32P1 | n.334+1033C>T | Intron (SNP) | VAF 44/170 reads (26%) | called by mutect2, varscan2
